Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABKV, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABKV-TTP1-A (Primary Tumor).

Material description

- A) Upper pulmonary lobe, right lung
- B) Pulmonary hilum, lymph node **N. 1**
- C) Intrascissural lymph node **N. 1**
- D) Paratracheal lymph nodes **N. 2**
- E) Subcarinal lymph nodes **N. 2**

ICD-0-3

adenocarcinoma, solid 8230/3
Site: (R) lung, upper lobe C34.1

ICD-10

C34.11

hw
2/10/16

Macro description

- A) 14x 11x 6 cm pulmonary lobe that, to 4 cm from the margin of bronchial resection, shows formation of 6,4 cm of bigger axis relatively well delimited, made up of whitish tissue, hard-elastic compactness, with large areas of necrosis that doesn't pass the visceral pleura.
- A1) Bronchial margin. A2,A3) Peribronchial lymph nodes, the largest of 2,2 cm of maximum size.
- A4-A7) Neoplasm. A8-A11) Further samples of neoplasm
- B) 2 lymph nodes, greater size of 2,1 cm
- C) 2 lymph nodes, greater size of 1,9 cm
- D) 2 irregular fragments, greater size of 1,8 cm
- E) A fragment of adipose tissue containing 4 lymph nodes

Micro description

Immunohistochemical arrangement of the neoplasm: CK7+; CEA +/- focal; TTF-1-(cytoplasmic positivity);calretinin -;synaptophysin -. We observe a few cytoplasmic vacuoles with material PASD+.

Diagnosis

A-E) Poorly differentiated lung adenocarcinoma ,solid type, that doesn't infiltrate the visceral pleura. Free the margin of surgical resection and the hilum lymph nodes , **N. 1** of hilum, **N. 1** intrascissural, **N.2** paratracheal and **N. 2** subcarinal

Lobectomy and limphadenectomy

Staging pTNM:

pT2,pNO,G3

Source: NCI Genomic Data Commons file 603acf8b-d2a0-430f-84e1-352655e674f4 (CDDP-ABKV-TTP1.11BEDF8E-672F-420E-85C3-48C72C209651.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).